Somatic mutation profile of tumor specimen TCGA-FF-A7CW-01A (aliquot TCGA-FF-A7CW-01A-11D-A382-10) from TCGA case TCGA-FF-A7CW, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 72.6 years (26,520 days).
Specimen TCGA-FF-A7CW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5550dff5-1961-4694-b827-afbbdc1689c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FF-A7CW-10A (Blood Derived Normal), aliquot TCGA-FF-A7CW-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1c4a7ee-3ae2-4618-a5f0-ce68191c0388

The open-access MAF lists 52 somatic variants for this specimen: 41 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 9, Nonsense Mutation 3, Frame Shift Del 3, Intron 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.4219G>A p.A1407T | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as rs189206655, COSV66064966; called by muse, mutect2, varscan2
- ADGRA3 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99293037; called by muse, mutect2, varscan2
- ASXL3 | c.4465G>A p.V1489I | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.03); catalogued as COSV99323852; called by muse, mutect2, varscan2
- BAZ2B | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 95/428 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs1369489415, COSV100600453; called by muse, mutect2, varscan2
- BRAP | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1208386063, COSV100554015, COSV59538101; called by muse, mutect2, varscan2
- CAMSAP2 | c.3002G>A p.R1001Q (on ENST00000236925 / NM_001297707.2; = p.R990Q on NM_203459.3) | Missense Mutation (SNP) | VAF 93/178 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs777933401, COSV99372995; called by muse, mutect2, varscan2
- CARD11 | c.1022T>A p.L341Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101210588; called by muse, mutect2, varscan2
- CBFB | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs1184665334, COSV52002779, COSV99325547; called by muse, varscan2
- CLCN1 | c.2918C>T p.P973L | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.997); catalogued as COSV100577799; called by muse, mutect2, varscan2
- CLSTN2 | c.1784C>T p.T595M | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368537354, COSV101515431; called by muse, mutect2, varscan2
- COLEC12 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV101231991; called by muse, mutect2, varscan2
- CSK | c.878A>G p.K293R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.123); catalogued as COSV99583492; called by muse, mutect2, varscan2
- CTNNA2 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1413474943, COSV58155571, COSV99057388; called by muse, mutect2, varscan2
- GLP2R | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs749983399, COSV52329638; called by muse, mutect2, varscan2
- GPR171 | c.670A>G p.N224D | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV99851978; called by muse, mutect2, varscan2
- H1-4 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99175232; called by muse, mutect2, varscan2
- IFRD2 | c.772G>C p.A258P | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100269329; called by muse, varscan2
- KLHL6 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548549593, COSV58068532, COSV58069328; called by muse, mutect2, varscan2
- KMT2D | c.6520C>T p.Q2174* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV56419557; called by muse, mutect2, varscan2
- LAMA3 | c.8378C>T p.A2793V (on ENST00000313654 / NM_198129.4; = p.A1184V on NM_000227.6) | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs1289464769, COSV99334158; called by muse, mutect2, varscan2
- MAGI2 | c.289T>A p.C97S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.192); catalogued as COSV100833539; called by muse, mutect2, varscan2
- MAP3K10 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs770231591, COSV99454103; called by muse, mutect2, varscan2
- MLXIP | c.577G>T p.V193L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV100038526; called by muse, mutect2, varscan2
- MPP7 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs746515776, COSV100517080; called by muse, mutect2, varscan2
- MRPS27 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54653483; called by muse, mutect2, varscan2
- POF1B | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 87/174 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs769700681, COSV53134884; called by muse, mutect2, varscan2
- PRKG1 | c.1754T>C p.I585T | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100907179; called by muse, mutect2, varscan2
- RC3H1 | c.700T>A p.F234I | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51202609, COSV99281129; called by muse, mutect2, varscan2
- RPS6KA6 | c.1729G>T p.G577* | Nonsense Mutation (SNP) | VAF 89/168 reads (53%) | catalogued as COSV99424079, COSV99424322; called by muse, mutect2, varscan2
- SMARCB1 | c.835A>C p.T279P (on ENST00000263121; = p.T325P on NM_003073.5) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV99574971; called by mutect2, varscan2
- SPANXN2 | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV100979835; called by muse, mutect2, varscan2
- SPATA5 | c.15_17del p.K5del | In Frame Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs1432376693; called by pindel, varscan2
- SPINDOC | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs373118347; called by muse, mutect2, varscan2
- TLL2 | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1324584580, COSV100780183; called by muse, mutect2, varscan2
- UGT2B7 | c.1455G>A p.W485* | Nonsense Mutation (SNP) | VAF 33/104 reads (32%) | catalogued as COSV100535129; called by muse, mutect2, varscan2
- UNC13B | c.1656G>T p.K552N | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV101036371; called by muse, mutect2
- ZC3H7A | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.475); catalogued as COSV100865475; called by muse, mutect2, varscan2
- ZNF479 | c.1346C>A p.S449Y | Missense Mutation (SNP) | VAF 116/320 reads (36%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.726); catalogued as COSV100482582; called by muse, mutect2, varscan2
- FRAS1 | c.493del p.V165Cfs*10 | Frame Shift Del (DEL) | VAF 25/129 reads (19%) | called by mutect2, pindel, varscan2
- LRTM2 | c.1043del p.K348Sfs*5 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- SLC35A2 | c.840_843del p.F280Lfs*68 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- COL14A1 | c.3120C>A p.S1040= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV99918366; called by muse, mutect2, varscan2
- EPG5 | c.2196C>T p.S732= | Silent (SNP) | VAF 25/146 reads (17%) | catalogued as rs775095237, COSV99956715; called by muse, mutect2, varscan2
- HSPG2 | c.5712C>T p.G1904= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs754407360, COSV101020481; called by muse, mutect2, varscan2
- LAMA1 | c.6075G>A p.T2025= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as rs766719038, COSV67534312; called by muse, mutect2, varscan2
- MRGPRF | c.426C>T p.C142= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs988081085, COSV100307795; called by muse, mutect2, varscan2
- MROH2B | c.1074A>C p.T358= | Silent (SNP) | VAF 39/142 reads (27%) | catalogued as rs1459676538, COSV101270588; called by muse, mutect2, varscan2
- PTCHD3 | c.30G>A p.P10= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs369428695; called by muse, mutect2, varscan2
- TPO | c.1698G>A p.V566= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100220092; called by muse, mutect2, varscan2
- XIAP | c.591A>G p.Q197= | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as COSV100848831, COSV63023594; called by muse, mutect2, varscan2
- LARP7 | c.1142+362A>G | Intron (SNP) | VAF 48/189 reads (25%) | catalogued as COSV100135019; called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331239 C>T | 5'Flank (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
